Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A87N, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A87N-01A (Primary Tumor).

Specimen Collected Date: [REDACTED] Specimen Received Date: [REDACTED]
Order Number: [REDACTED] Ordering Provider: [REDACTED]
Medical Record Number: [REDACTED] Facility: [REDACTED]
Status: [REDACTED]

ICD-O-3

Astrocytoma, grade III
9401/3Sub ^{C6CE} Brain, supratentorial NOS C71.0
^{path} Brain, frontal lobe C71.1

Accession #: [REDACTED]
Pathologist: [REDACTED]
Date of Procedure: [REDACTED]
Date Received: [REDACTED]
Date Reported: [REDACTED]
Submitting Physician: [REDACTED]
Location: [REDACTED]

Addendum Present

FINAL DIAGNOSIS

A. LEFT FRONTAL LOBE OF BRAIN, TUMOR, REMOVAL:
-ANAPLASTIC ASTROCYTOMA (WHO GRADE III).

Note: Focal oligodendroglia differentiation is identified. Immunohistochemical staining for [REDACTED] is positive. An addendum will be issued pending analyses for the lesions on chromosomes 1 and 19.

Note

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's).

ASR's

have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the [REDACTED]. The FDA does not require this test to go through premarket FDA review. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing. The assays were performed with appropriate positive and negative controls which stained appropriately.

Electronically Signed Out By [REDACTED]

Addendum/Procedures:

Addendum Date Ordered: [REDACTED] Status: Signed Out
Date Complete: [REDACTED]
Date Reported: [REDACTED]

Addendum Diagnosis

Fluorescence in situ hybridization, performed at [REDACTED]
demonstrates preservation of both chromosomes 1p and 19q.

Electronically Signed Out By [REDACTED]

Clinical History:

(1) brain tumor

Specimens Submitted As:

A: LEFT FRONTAL BRAIN TUMOR

Gross Description:

Received in formalin, labeled with lesions name and number, are multiple segments of irregular, opaque white to tan-brown, soft cerebriform tissue measuring in aggregate 2.3 x 1.8 x 0.5 cm. Submitted in toto in one cassette.

Source: NCI Genomic Data Commons file 572c2438-5375-4ac7-a313-e8db188f5163 (TCGA-FG-A87N.061C4D2D-340B-4F59-9B6F-C552E4BF75C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).